Somatic mutation profile of tumor specimen TCGA-BP-4963-01A (aliquot TCGA-BP-4963-01A-01D-1462-08) from TCGA case TCGA-BP-4963, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 64.0 years (23,373 days).
Specimen TCGA-BP-4963-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7303c28e-8026-4257-bc21-ccf974a1b8fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4963-11A (Solid Tissue Normal), aliquot TCGA-BP-4963-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8307fb-7ff7-4190-a5dc-8448f73c1384

The open-access MAF lists 99 somatic variants for this specimen: 70 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 26, Frame Shift Del 8, Frame Shift Ins 7, Splice Site 2, Intron 2, Nonsense Mutation 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008676.3 | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56636008; called by muse, mutect2
- ADGRE3 | c.1690A>T p.T564S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as COSV53728822; called by muse, mutect2, varscan2
- ALG10 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 77/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56791977; called by muse, mutect2, varscan2
- ALLC | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV52993374; called by muse, mutect2, varscan2
- AP3D1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.087); catalogued as rs371117784; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV63437254; called by muse, mutect2, varscan2
- ASPSCR1 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV60727598; called by muse, mutect2, varscan2
- ATP7B | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); catalogued as rs1375281491, COSV54436084, COSV54438755; called by muse, mutect2, varscan2
- CCDC47 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1417608720, COSV56722246; called by muse, mutect2, varscan2
- CLSTN3 | c.1948C>A p.H650N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV56934580; called by muse, mutect2, varscan2
- CNTNAP2 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs200673864, COSV62154527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL3 | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.295); catalogued as COSV52362327; called by muse, mutect2, varscan2
- DDX46 | c.1626G>A p.Q542= | Splice Region (SNP) | VAF 28/163 reads (17%) | catalogued as COSV62798695; called by muse, mutect2, varscan2
- DNAAF5 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs779352236, COSV52414902; called by muse, mutect2, varscan2
- DNAJC2 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 124/305 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV50789732; called by muse, mutect2, varscan2
- DOCK8 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66633090; called by muse, mutect2, varscan2
- DOCK8 | c.1619C>A p.P540Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66633102; called by muse, mutect2, varscan2
- DONSON | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV51676527; called by mutect2, varscan2
- DUOX1 | c.4124A>T p.Q1375L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV52049739; called by muse, mutect2, varscan2
- EPHB1 | c.2644A>T p.I882F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV67655886; called by muse, mutect2, varscan2
- EXTL3 | c.1946A>C p.E649A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV55037164; called by muse, mutect2, varscan2
- FAM210A | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV59183659; called by muse, mutect2, varscan2
- FBXW8 | c.967A>C p.K323Q (on ENST00000309909; = p.K361Q on NM_012174.1) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV59297190; called by muse, mutect2
- GLI2 | c.4226C>T p.S1409L (on ENST00000361492 / NM_001374353.1; = p.S1426L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.3); catalogued as rs1215590067, COSV58035786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR65 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV50862408; called by muse, mutect2, varscan2
- KRT36 | c.918G>T p.Q306H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV60202737, COSV60203412; called by muse, mutect2
- LEPR | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV60749216; called by muse, mutect2, varscan2
- MMEL1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV56519258; called by muse, varscan2
- MPZL1 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63256100; called by muse, mutect2, varscan2
- MS4A12 | c.249C>A p.N83K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV50014153; called by muse, mutect2, varscan2
- MYL7 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV56267432, COSV56268968, COSV56269180; called by muse, mutect2, varscan2
- NSD3 | c.3767A>C p.E1256A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57667843; called by muse, mutect2, varscan2
- PBRM1 | c.842del p.Y281Lfs*2 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as COSV56261414, COSV56277417, COSV56277431; called by mutect2, pindel
- PCLO | c.6475C>T p.H2159Y | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV61621777; called by muse, mutect2, varscan2
- PIGQ | c.2077G>T p.G693C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as COSV50312455; called by muse, mutect2, varscan2
- PIP4K2A | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs771178304, COSV64862383; called by muse, mutect2, varscan2
- PLXNA4 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV58110959; called by muse, mutect2, varscan2
- PPP4R3B | c.883A>T p.I295F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV55402537; called by muse, mutect2, varscan2
- PRAG1 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs199973377, COSV58158780; called by muse, mutect2, varscan2
- RPRD2 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs868989316, COSV64818986; called by muse, mutect2, varscan2
- RYR1 | c.11515A>G p.S3839G | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1227981044, COSV62091737; called by muse, mutect2, varscan2
- SCAF8 | c.3309G>T p.E1103D | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.017); catalogued as COSV65790595; called by muse, mutect2, varscan2
- SETD2 | c.5606A>T p.D1869V | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57432480; called by muse, varscan2
- SIM2 | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51766706; called by muse, mutect2, varscan2
- SLAMF7 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs781511925, COSV63562853; called by muse, mutect2, varscan2
- SMARCA4 | c.2439-1G>A p.X813_splice | Splice Site (SNP) | VAF 46/152 reads (30%) | catalogued as COSV60789314; called by muse, mutect2, varscan2
- SMARCAL1 | c.638G>C p.S213T | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV61920237; called by muse, mutect2, varscan2
- TNRC6C | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV56941992; called by muse, mutect2, varscan2
- TRPM2 | c.4237T>A p.S1413T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55967094; called by muse, mutect2, varscan2
- UBXN11 | c.418G>C p.V140L (on ENST00000374221 / NM_183008.2; = p.V107L on NM_145345.2) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV59024720; called by muse, mutect2
- UNC13C | c.4581G>A p.M1527I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV52850528; called by muse, mutect2, varscan2
- ZXDC | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV67628277; called by muse, mutect2, varscan2
- ARFGEF1 | c.4085A>G p.K1362R | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- ASIC2 | c.680_687del p.E227Afs*12 | Frame Shift Del (DEL) | VAF 37/150 reads (25%) | called by mutect2, pindel, varscan2
- B3GAT2 | c.930C>G p.N310K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BOP1 | c.1980A>T p.R660S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CANX | c.1182+1dup | Frame Shift Ins (INS) | VAF 52/329 reads (16%) | called by mutect2, pindel, varscan2
- CLRN3 | c.346_347insCGCA p.I116Tfs*57 | Frame Shift Ins (INS) | VAF 30/112 reads (27%) | called by mutect2, pindel, varscan2
- EIF2AK2 | c.373del p.V125Cfs*48 | Frame Shift Del (DEL) | VAF 59/314 reads (19%) | called by mutect2, pindel, varscan2
- EXOC1 | c.1375+2del p.X459_splice | Splice Site (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- HMOX1 | c.242_249del p.E81Afs*57 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1583del p.G528Vfs*50 | Frame Shift Del (DEL) | VAF 23/135 reads (17%) | called by mutect2, pindel, varscan2
- OR8G5 | c.147dup p.G50Wfs*21 | Frame Shift Ins (INS) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- SETD2 | c.5617_5627del p.P1873Nfs*10 | Frame Shift Del (DEL) | VAF 56/216 reads (26%) | called by pindel, varscan2
- SLC35A5 | c.431_432insA p.R145Afs*25 | Frame Shift Ins (INS) | VAF 30/122 reads (25%) | called by mutect2, pindel
- SLC39A3 | c.125del p.K42Rfs*26 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel, varscan2
- USH2A | c.7940dup p.T2648Yfs*13 | Frame Shift Ins (INS) | VAF 18/146 reads (12%) | called by mutect2, varscan2
- VHL | c.501_502delinsT p.S168Afs*2 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by pindel, varscan2*
- XRCC4 | c.353dup p.N118Kfs*4 | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- ZNF250 | c.767dup p.C257Vfs*2 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- BRCA2 | c.2985A>T p.G995= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV66449967; called by muse, mutect2, varscan2
- CFH | c.2928A>G p.E976= | Silent (SNP) | VAF 10/256 reads (4%) | catalogued as COSV66406584; called by muse, mutect2
- CHD7 | c.7395T>C p.F2465= | Silent (SNP) | VAF 48/215 reads (22%) | catalogued as COSV71107713; called by muse, mutect2, varscan2
- EDDM3B | c.390C>T p.D130= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs762396483, COSV58746686; called by muse, mutect2, varscan2
- EPN2 | c.285G>A p.Q95= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV59060283; called by muse, mutect2, varscan2
- FBN1 | c.3468C>T p.I1156= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV57311573; called by muse, mutect2, varscan2
- FBXW8 | c.966G>A p.L322= (on ENST00000309909; = p.L360= on NM_012174.1) | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV59297155, COSV59304104; called by muse, mutect2
- GPATCH8 | c.1815C>T p.G605= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV59193647; called by muse, mutect2, varscan2
- IGHG4 | c.894G>A p.Q298= | Silent (SNP) | VAF 50/272 reads (18%) | called by muse, varscan2
- LRRK1 | c.4482A>T p.R1494= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV52604470; called by muse, mutect2, varscan2
- MAPRE3 | c.15G>A p.V5= | Silent (SNP) | VAF 73/314 reads (23%) | catalogued as COSV51866418; called by muse, mutect2, varscan2
- MARS2 | c.1314G>A p.P438= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as rs768592476, COSV56570870; called by muse, mutect2, varscan2
- MBOAT1 | c.369C>T p.I123= | Silent (SNP) | VAF 49/213 reads (23%) | catalogued as COSV61123985; called by muse, mutect2, varscan2
- MFHAS1 | c.2341C>A p.R781= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV52280441; called by muse, mutect2, varscan2
- NLK | c.570T>C p.C190= | Silent (SNP) | VAF 48/166 reads (29%) | catalogued as COSV69407880; called by muse, mutect2, varscan2
- NUMB | c.1128T>C p.L376= (on ENST00000355058; = p.L365= on NM_003744.5) | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV61567905; called by muse, mutect2, varscan2
- PLS3 | c.1479G>C p.L493= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV56776797; called by muse, mutect2, varscan2
- PRPF19 | c.1458C>T p.H486= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs751325779, COSV57127199; called by muse, mutect2, varscan2
- RTN4RL1 | c.213C>A p.P71= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs757441487, COSV58674686; called by muse, mutect2, varscan2
- SLC25A44 | c.243C>A p.T81= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV63961549; called by muse, mutect2, varscan2
- SLC39A1 | c.906G>A p.R302= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV57841419; called by muse, mutect2, varscan2
- SPZ1 | c.789G>A p.E263= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV57062558; called by muse, mutect2, varscan2
- STYK1 | c.1245C>G p.L415= | Silent (SNP) | VAF 144/378 reads (38%) | catalogued as COSV50012575, COSV50014567; called by muse, mutect2, varscan2
- TP63 | c.1458G>A p.Q486= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV53199415; called by muse, mutect2, varscan2
- USP34 | c.2520T>C p.H840= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV68399328; called by muse, mutect2, varscan2
- VAV1 | c.2292C>T p.P764= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV58380087; called by muse, mutect2, varscan2
- EEF1D | c.-7-2889A>T | Intron (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100414807; called by muse, mutect2, varscan2
- EEF1D | c.-7-2890G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100414809; called by muse, varscan2
- PCDH12 | c.-1C>A | 5'UTR (SNP) | VAF 21/133 reads (16%) | catalogued as COSV99189370; called by muse, mutect2, varscan2
